Gene-level copy-number profile of specimen HCM-SANG-0530-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0530-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0530-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e81dc1fd-ebd3-460b-ab0c-f8575e57040e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0530-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/c986ea12-60e8-4f03-beaa-3758f9e0178c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,006; copy number 2: 28,440; copy number 3: 25,700; copy number 4: 1,810; copy number 5: 199; copy number 6: 252; copy number 7: 4; copy number 8: 458; copy number 11: 26; copy number 21: 4; copy number 38: 2; copy number 47: 3.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–3): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 948 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,365,253–31,583,306, 7 genes, copy number 5 (within-gene range 3–5): FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226.
- chr1:190,478,551–190,494,297, 2 genes, copy number 5: LINC01351, AL391645.1.
- chr1:234,724,042–235,074,220, 9 genes, copy number 6: LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348.
- chr3:133,551,186–133,754,576, 6 genes, copy number 5 (within-gene range 3–5): AC022296.1, CDV3, TOPBP1, INHCAP, RNU6-678P, RNA5SP140.
- chr6:30,617,840–31,059,890, 35 genes, copy number 5 (within-gene range 3–5): MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22.
- chr7:6,952,625–7,104,482, 4 genes, copy number 6: AC079804.3, MIR3683, AC092104.1, Y_RNA.
- chr8:56,638,894–58,659,853, 30 genes, copy number 5–7: AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1.
- chr8:61,500,556–61,714,640, 1 gene, copy number 5 (within-gene range 3–5): ASPH.
- chr8:61,631,680–61,944,180, 7 genes, copy number 5: RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3.
- chr8:71,197,433–71,592,025, 2 genes, copy number 5 (within-gene range 3–5): EYA1, TRAPPC2P2.
- chr9:61,190,003–61,453,030, 7 genes, copy number 8: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:114,060,127–114,078,328, 1 gene, copy number 5: AMBP.
- chr15:78,250,502–78,383,155, 10 genes, copy number 5: AC090607.3, DNAJA4, WDR61, AC090607.4, AC090607.2, AC090607.1, AC090607.5, AC011270.2, CRABP1, AC011270.1.
- chr16:9,068,554–9,156,881, 5 genes, copy number 5: AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119.
- chr18:21,612,314–22,348,252, 28 genes, copy number 5: SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.
- chr18:22,586,465–23,486,603, 16 genes, copy number 5: RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1.
- chr19:29,811,991–37,304,395, 264 genes, copy number 8–11 (broad region; genes not listed).
- chr20:24,949,269–25,149,372, 9 genes, copy number 5: CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2.
- chr20:40,031,585–40,854,229, 5 genes, copy number 5: AL133419.1, AL009050.1, MAFB, AL035665.1, RNA5SP484.
- chr20:43,189,998–44,696,096, 45 genes, copy number 8 (within-gene range 2–8): AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1.
- chr20:44,885,702–48,494,309, 126 genes, copy number 8 (broad region; genes not listed).
- chr20:49,046,246–52,862,855, 81 genes, copy number 5–8 (broad region; genes not listed).
- chr20:53,255,979–53,668,758, 9 genes, copy number 21–47 (within-gene range 4–47): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P.
- chr20:54,859,688–64,033,100, 239 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
